Gene-level copy-number profile of tumor specimen TCGA-FM-8000-01A from TCGA case TCGA-FM-8000, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 70.4 years (25,724 days).
Specimen TCGA-FM-8000-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-DLBC.447f9c21-4fe0-4b52-a5d5-78668e443665.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FM-8000-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7d2c9f51-81e7-4e56-93fb-2f70be43df36

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 118; copy number 1: 383; copy number 2: 51,812; copy number 3: 7,440; copy number 7: 55.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FM-8000-01A-11D-2209-01): tumor purity 0.8, ploidy 2.12, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 118 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene (within-gene range 0–2): AC244205.1.
- chr2:88,857,161–89,254,015, 40 genes: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr17:64,940,602–65,056,740, 5 genes: AC037487.4, SLC16A6P1, AMZ2P1, GNA13, AC037487.2.
- chr22:22,420,326–22,915,927, 72 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 55 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:57,907,629–61,538,741, 55 genes, copy number 7 (within-gene range 2–7): VRK2, AC068193.1, FANCL, AC007250.1, EIF3FP3, LINC01795, LINC01122, AC007238.1, AC007092.1, LINC01793, AC007100.1, AC007179.2, AC007179.1, AC007179.3, RNU6-508P, RNA5SP94, AC007100.2, AC007132.1, MIR4432HG, AC007381.1, RNU1-32P, MIR4432, BCL11A, AC009970.1, RN7SL361P, IFITM3P9, RPL26P13, RNU6-612P, ATP1B3P1, PAPOLG, LINC01185, RN7SL632P, RPL21P33, REL, RNU4-51P, AC010733.1, NONOP2, RPS12P3, PUS10, RNA5SP95, PEX13, KIAA1841, AC016747.4, AC016747.1, C2orf74, AC016747.2, AHSA2P, USP34, AC016747.3, AC018889.1, AC016894.1, SNORA70B, AC016727.1, XPO1, AC016727.3.

Autosomal genes at a single copy (total copy number 1): 383. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
